Gene-level copy-number profile of tumor specimen TCGA-EJ-8470-01A from TCGA case TCGA-EJ-8470, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.1 years (21,209 days).
Specimen TCGA-EJ-8470-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.5ac39210-a0ab-40c3-b0bf-e4bbd47abaee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-8470-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7ea40bb9-ebc6-442c-9850-76c880eea934

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 7,479; copy number 2: 52,308.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-8470-01A-11D-2391-01): tumor purity 0.45, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:105,922,994–107,195,332, 6 genes: RNA5SP189, AC027313.1, AC114940.1, AC114940.2, LINC01950, PSMC1P5.
- chr5:109,165,289–109,326,369, 2 genes: AC116428.1, AC008467.1.
- chr6:94,163,920–94,447,179, 5 genes: AL157378.1, AL078595.1, AL078595.3, AL078595.2, MTCYBP36.
- chr12:33,374,238–34,249,958, 18 genes: SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,092. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
